Somatic mutation profile of tumor specimen BA2358D (aliquot aq-BA2358D) from BEATAML1.0 case 2423, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 76.0 years (27,758 days).
Specimen BA2358D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b1c3e96-a8ef-4345-8a8a-aa37b557deeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2854D (Solid Tissue Normal), aliquot aq-BA2854D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31fb46f3-b646-4a12-a192-faeee1117597

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 3, Splice Site 2, Intron 2, Nonsense Mutation 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 67/343 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs121913502, CM106818, COSV57468751, COSV57469541; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- SRSF2 | c.284C>G p.P95R | Missense Mutation (SNP) | VAF 34/90 reads (38%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen probably damaging (0.987); catalogued as rs751713049, CM1511359, COSV57969809, COSV57969816, COSV57969830; called by mutect2, varscan2
- BHMT | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs543295195; called by muse, mutect2, varscan2
- CDC42BPB | c.4621G>T p.D1541Y | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV63476427; called by muse, mutect2, varscan2
- FGF23 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); catalogued as rs371972859, COSV52976575; called by muse, mutect2, varscan2
- IGF2BP3 | c.562G>A p.V188I | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.36); PolyPhen benign (0.048); catalogued as rs765538897, COSV51688478; called by muse, mutect2, varscan2
- NEBL | c.2012C>A p.P671Q | Missense Mutation (SNP) | VAF 50/190 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV65803191; called by muse, mutect2, varscan2
- PLEKHG6 | c.1091C>T p.A364V | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs145264028; called by muse, varscan2
- PREX2 | c.2723G>A p.R908H | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.644); catalogued as rs201443824; called by muse, mutect2, varscan2
- SLC22A12 | c.506+1G>A p.X169_splice | Splice Site (SNP) | VAF 24/89 reads (27%) | catalogued as rs58174038, CS043649; called by muse, mutect2, varscan2
- ATG9B | c.2341G>T p.D781Y | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- ATP1A2 | c.2036T>G p.L679R | Missense Mutation (SNP) | VAF 93/361 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- KLHL13 | c.1273G>T p.A425S | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- KMT2C | c.3515dup p.Y1172* | Nonsense Mutation (INS) | VAF 8/67 reads (12%) | called by mutect2, pindel, varscan2
- L1CAM | c.1247A>G p.N416S | Missense Mutation (SNP) | VAF 40/187 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAPKAP1 | c.498+1G>A p.X166_splice | Splice Site (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- NAV2 | c.6581A>G p.H2194R (on ENST00000396087 / NM_001244963.2; = p.H2135R on NM_145117.5) | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); called by muse, mutect2
- PDCD11 | c.40del p.R14Efs*44 | Frame Shift Del (DEL) | VAF 44/219 reads (20%) | called by mutect2, pindel, varscan2
- RUNX1 | c.1228A>G p.T410A (on ENST00000344691 / NM_001001890.3; = p.T437A on NM_001754.5) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.388); called by muse, varscan2
- USP26 | c.2219A>T p.Q740L | Missense Mutation (SNP) | VAF 100/334 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- MRGPRD | c.729G>T p.V243= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- PCARE | c.2676G>T p.L892= | Silent (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- UNC45B | c.2757C>A p.I919= | Silent (SNP) | VAF 24/100 reads (24%) | called by muse, mutect2, varscan2
- DKC1 | c.1260-112C>T | Intron (SNP) | VAF 44/193 reads (23%) | catalogued as rs1378553668; called by muse, mutect2, varscan2
- PTPRR | c.628-432T>C | Intron (SNP) | VAF 22/85 reads (26%) | called by muse, varscan2
